Somatic mutation profile of tumor specimen TCGA-06-0876-01A (aliquot TCGA-06-0876-01A-01D-1492-08) from TCGA case TCGA-06-0876, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 72.2 years (26,372 days).
Specimen TCGA-06-0876-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c99dbf5-43a9-4854-83db-fef826e524a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0876-10A (Blood Derived Normal), aliquot TCGA-06-0876-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e160d5a-1896-4bc3-89be-02550078b262

The open-access MAF lists 68 somatic variants for this specimen: 50 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 17, Nonsense Mutation 5, Frame Shift Del 2, Splice Site 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCX | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 74/182 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs587783562, CM980528, COSV57565678; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EGFR | c.323G>A p.R108K | Missense Mutation (SNP) | VAF 854/2719 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519828, COSV51766433; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EGFR | c.866C>A p.A289D | Missense Mutation (SNP) | VAF 289/3134 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 1082/3497 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 30/83 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AHR | c.422C>A p.T141N | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as COSV54121466; called by muse, mutect2
- ANKDD1A | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.207); catalogued as rs377565868; called by muse, mutect2, varscan2
- ARMCX2 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 121/313 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.055); catalogued as COSV57529143; called by muse, mutect2, varscan2
- CENPF | c.7066G>A p.A2356T | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV65272502; called by muse, mutect2, varscan2
- CFAP77 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58006990; called by muse, mutect2, varscan2
- CHAT | c.2164T>C p.C722R | Missense Mutation (SNP) | VAF 122/179 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60319750; called by muse, mutect2, varscan2
- CNGA2 | c.1512T>A p.D504E | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.068); catalogued as COSV61703018, COSV61706067; called by muse, mutect2, varscan2
- COL27A1 | c.3157C>T p.R1053* | Nonsense Mutation (SNP) | VAF 21/62 reads (34%) | catalogued as COSV61921243; called by muse, mutect2, varscan2
- COL4A1 | c.4133G>A p.G1378D | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM1110741, COSV65420935; called by muse, mutect2, varscan2
- CSMD2 | c.6538+1G>A p.X2180_splice | Splice Site (SNP) | VAF 13/48 reads (27%) | catalogued as rs1557608442, COSV53912091; called by muse, mutect2
- CTSW | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.403); catalogued as COSV57171639; called by muse, varscan2
- DCDC1 | c.4156C>T p.R1386C (on ENST00000597505 / NM_001367979.1; = p.R493C on NM_020869.3) | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.555); catalogued as rs201587746, COSV58000770; called by muse, mutect2, varscan2
- DLGAP2 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.53); catalogued as COSV70093716; called by muse, mutect2, varscan2
- DOCK8 | c.3095C>G p.A1032G | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV66617448; called by muse, mutect2, varscan2
- DOCK8 | c.3175C>G p.L1059V | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV66617455; called by muse, mutect2, varscan2
- DPT | c.538A>T p.R180W | Missense Mutation (SNP) | VAF 75/202 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63189483; called by muse, mutect2, varscan2
- DYNAP | c.414C>A p.N138K (on ENST00000321600; = p.N112K on NM_173629.3) | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as rs1331210288, COSV58665936; called by muse, mutect2, varscan2
- EPS8L3 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV62608695; called by muse, mutect2, varscan2
- FHDC1 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.453); catalogued as rs149221149; called by muse, mutect2, varscan2
- IFNG | c.334C>T p.R112* | Nonsense Mutation (SNP) | VAF 83/233 reads (36%) | catalogued as COSV57490528; called by muse, mutect2, varscan2
- IGKV1-6 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 107/292 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as rs766584300; called by muse, mutect2, varscan2
- KLF1 | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs777110892, COSV53434412; called by muse, mutect2, varscan2
- LPIN3 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as rs747237851, COSV64718247; called by muse, mutect2, varscan2
- LRRC8B | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV58372919; called by muse, mutect2, varscan2
- MUC3A | c.8484T>A p.Y2828* | Nonsense Mutation (SNP) | VAF 148/980 reads (15%) | catalogued as COSV100113748; called by muse, mutect2, varscan2
- N4BP2L2 | c.2305C>T p.Q769* (on ENST00000674422; = p.Q340* on NM_033111.4) | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as COSV62631424; called by muse, mutect2, varscan2
- NR3C2 | c.740G>A p.R247K | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.033); catalogued as COSV60985062; called by muse, mutect2, varscan2
- OR2K2 | c.295G>A p.D99N (on ENST00000374428; = p.D70N on NM_205859.2) | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57016072; called by muse, mutect2, varscan2
- OR6C70 | c.220G>T p.A74S | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs749540632, COSV59244469, COSV59245508; called by muse, mutect2, varscan2
- PCDHA2 | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 86/232 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.453); catalogued as rs782095286, COSV65366989; called by muse, mutect2, varscan2
- PI4KA | c.658C>G p.L220V | Missense Mutation (SNP) | VAF 83/272 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV55403434; called by muse, mutect2, varscan2
- POU4F2 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV55583953; called by muse, mutect2, varscan2
- PTEN | c.136T>C p.Y46H | Missense Mutation (SNP) | VAF 51/73 reads (70%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV64296748, COSV64297491; called by muse, mutect2, varscan2
- PXN | c.1465T>G p.S489A (on ENST00000228307 / NM_001080855.3; = p.S455A on NM_002859.4) | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV57218775; called by muse, mutect2
- RGS14 | c.866T>C p.L289P | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.642); catalogued as rs775508379, COSV68770837; called by muse, mutect2, varscan2
- SDCBP | c.750G>A p.K250= | Splice Region (SNP) | VAF 62/174 reads (36%) | catalogued as COSV50683645; called by muse, mutect2, varscan2
- SEMG1 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs199672858, COSV54871705, COSV54872099; called by muse, mutect2, varscan2
- SERPINB12 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 152/415 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs770606706, COSV54032059; called by muse, mutect2, varscan2
- SLC38A5 | c.929C>A p.T310N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as COSV58333273; called by muse, mutect2
- TTC13 | c.1801del p.I601Lfs*3 | Frame Shift Del (DEL) | VAF 60/180 reads (33%) | catalogued as COSV64167701; called by mutect2, pindel, varscan2
- WNT2 | c.307C>T p.R103* | Nonsense Mutation (SNP) | VAF 11/68 reads (16%) | catalogued as rs1399950382, COSV55411015; called by muse, mutect2, varscan2
- ZKSCAN1 | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 34/211 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV60874017; called by muse, mutect2, varscan2
- ZKSCAN4 | c.1508T>C p.I503T | Missense Mutation (SNP) | VAF 69/170 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.346); catalogued as rs968209334, COSV66022998; called by muse, mutect2, varscan2
- ZNFX1 | c.3775A>C p.M1259L | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV65593956; called by muse, mutect2, varscan2
- CLSPN | c.730_734del p.V244Kfs*17 | Frame Shift Del (DEL) | VAF 18/73 reads (25%) | called by mutect2, pindel, varscan2
- ADAMDEC1 | c.579C>T p.D193= | Silent (SNP) | VAF 73/292 reads (25%) | catalogued as rs141288918; called by muse, mutect2, varscan2
- ADRA1B | c.114C>T p.P38= | Silent (SNP) | VAF 90/219 reads (41%) | catalogued as COSV60700464; called by muse, mutect2, varscan2
- AIPL1 | c.87C>T p.T29= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as COSV51505808; called by muse, mutect2, varscan2
- AMMECR1L | c.255G>T p.A85= | Silent (SNP) | VAF 63/223 reads (28%) | catalogued as rs563618984, COSV55759851; called by muse, mutect2, varscan2
- ARSF | c.1260G>A p.Q420= | Silent (SNP) | VAF 56/125 reads (45%) | catalogued as COSV63838891; called by muse, mutect2, varscan2
- BCOR | c.3192G>A p.S1064= | Silent (SNP) | VAF 13/179 reads (7%) | catalogued as rs761604189, COSV60707220; called by muse, mutect2
- CD33 | c.321C>T p.D107= | Silent (SNP) | VAF 56/126 reads (44%) | catalogued as rs141721735; called by muse, mutect2, varscan2
- HHAT | c.963C>T p.L321= | Silent (SNP) | VAF 51/156 reads (33%) | catalogued as COSV54790973; called by muse, mutect2, varscan2
- HUWE1 | c.10881C>T p.A3627= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as rs1351146606, COSV53333861; called by muse, mutect2, varscan2
- KRTAP10-8 | c.402C>T p.C134= | Silent (SNP) | VAF 24/284 reads (8%) | catalogued as rs782140997, COSV58166322; called by muse, mutect2
- NRK | c.1476G>A p.Q492= | Silent (SNP) | VAF 27/97 reads (28%) | catalogued as COSV54596589; called by muse, mutect2, varscan2
- OR4X2 | c.201C>T p.S67= | Silent (SNP) | VAF 61/173 reads (35%) | catalogued as rs773448537, COSV56582035, COSV56585087; called by muse, mutect2, varscan2
- PCDHB14 | c.1779C>T p.D593= | Silent (SNP) | VAF 32/203 reads (16%) | catalogued as rs1294389040, COSV99505406; called by muse, mutect2, varscan2
- RAPGEF5 | c.1581C>T p.I527= (on ENST00000401957 / NM_001367602.2; = p.I830= on NM_012294.5) | Silent (SNP) | VAF 46/154 reads (30%) | catalogued as rs763409889, COSV59782931; called by muse, mutect2, varscan2
- SIGLEC9 | c.741C>T p.D247= | Silent (SNP) | VAF 51/140 reads (36%) | catalogued as rs774357117, COSV51582435, COSV51585838; called by muse, mutect2, varscan2
- SOWAHD | c.858G>A p.S286= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as rs1219284491, COSV59649412; called by muse, mutect2, varscan2
- ZNF208 | c.2226T>C p.I742= | Silent (SNP) | VAF 33/137 reads (24%) | catalogued as COSV68105502; called by muse, mutect2, varscan2
- TRIM10 | c.*217G>A | 3'UTR (SNP) | VAF 15/51 reads (29%) | catalogued as COSV64998070; called by muse, mutect2, varscan2
